Somatic mutation profile of tumor specimen TCGA-QG-A5YV-01A (aliquot TCGA-QG-A5YV-01A-11D-A28G-10) from TCGA case TCGA-QG-A5YV, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 64.3 years (23,499 days).
Specimen TCGA-QG-A5YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 779a2c49-3ca1-43c9-8152-e4b60c1aaa74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QG-A5YV-10A (Blood Derived Normal), aliquot TCGA-QG-A5YV-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f5f87dd-6a37-4e53-9699-cabb236ee337

The open-access MAF lists 182 somatic variants for this specimen: 135 protein-altering or splice-affecting, 38 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 38, Frame Shift Del 5, 3'UTR 4, Frame Shift Ins 4, Nonsense Mutation 4, Intron 3, Splice Region 3, Splice Site 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 55/131 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 66/107 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs751167134, COSV54439652; called by muse, mutect2
- ADGRG4 | c.7277+1G>C p.X2426_splice | Splice Site (SNP) | VAF 46/121 reads (38%) | catalogued as rs1404941340, COSV99794077; called by muse, mutect2, varscan2
- AGAP1 | c.2221G>A p.A741T (on ENST00000304032 / NM_001037131.3; = p.A688T on NM_014914.5) | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.403); catalogued as rs765171126, COSV100367494; called by muse, mutect2, varscan2
- ARHGEF9 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs781899711; called by muse, mutect2, varscan2
- ARMC4 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs185614747, COSV59469540; called by muse, mutect2, varscan2
- ASB13 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100731322; called by muse, mutect2, varscan2
- ASB2 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1490594774; called by muse, mutect2, varscan2
- ATCAY | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1199162322; called by muse, mutect2, varscan2
- ATP1B4 | c.894C>A p.Y298* (on ENST00000218008 / NM_001142447.3; = p.Y294* on NM_012069.5) | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as rs756223782; called by muse, mutect2, varscan2
- C1orf167 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1052471505; called by muse, mutect2, varscan2
- CACNB3 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as rs768890638, COSV56398491, COSV99974956; called by muse, mutect2, varscan2
- CCKAR | c.981G>T p.M327I | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV55162694; called by muse, mutect2
- COL18A1 | c.4222C>T p.P1408S (on ENST00000359759 / NM_130444.3; = p.P1173S on NM_030582.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs778025746, COSV100644899; called by muse, mutect2
- CUL3 | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52364446; called by muse, mutect2, varscan2
- DHX37 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs371053198; called by muse, mutect2
- DIAPH1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as COSV99525648; called by muse, varscan2
- DIP2A | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs776472944, COSV59471057; called by muse, mutect2, varscan2
- DXO | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs567817660, COSV100514503; called by muse, mutect2
- FAM186A | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs778582786, COSV59250544; called by muse, mutect2, varscan2
- FBN3 | c.4312C>T p.R1438* | Nonsense Mutation (SNP) | VAF 48/140 reads (34%) | catalogued as rs201582980; called by muse, mutect2, varscan2
- GJB1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs201697702, COSV100661228; ClinVar: benign; called by muse, mutect2
- GPM6A | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs116256200, COSV54537181; called by muse, mutect2, varscan2
- GRIP2 | c.1366G>A p.V456M (on ENST00000619221; = p.V359M on NM_001080423.4) | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs532400436, COSV56120489; called by muse, mutect2, varscan2
- GRXCR1 | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as rs746584226, COSV67670168, COSV67674256; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | catalogued as rs754199513; called by mutect2, varscan2
- HSPA6 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs781574993, COSV59061457; called by muse, mutect2, varscan2
- IL17RA | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772844479, COSV100082772; called by muse, mutect2
- ITGA7 | c.2328G>A p.A776= (on ENST00000555728; = p.A732= on NM_002206.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 12/92 reads (13%) | catalogued as rs778202604, COSV57698024, COSV57703726; called by muse, mutect2, varscan2
- JHY | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761262490, COSV99912513; called by muse, mutect2, varscan2
- KAT2B | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV99769034; called by muse, mutect2, varscan2
- KCNQ4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100714274, COSV61272307; called by muse, mutect2, varscan2
- KCNV2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs377471498, COSV66055783; called by muse, mutect2, varscan2
- KIF21B | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs763912127, COSV59755544; called by muse, mutect2, varscan2
- KIF3A | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs906443000, COSV66415651; called by muse, varscan2
- KLK13 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); catalogued as rs372211156; called by muse, mutect2, varscan2
- KMT2B | c.6428C>A p.A2143D | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs11670996; called by muse, mutect2, varscan2
- KRTAP12-3 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs201241084, COSV59970464; called by muse, mutect2, varscan2
- LRIT2 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs759472432; called by muse, mutect2
- MAGEB5 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66869014; called by muse, mutect2, varscan2
- MAP3K3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as rs901861960, COSV62281291; called by muse, mutect2, varscan2
- MBD3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as COSV50086690; called by muse, mutect2, varscan2
- METTL15 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1444277987; called by muse, mutect2, varscan2
- MGAT3 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV57863879; called by muse, mutect2, varscan2
- MIDEAS | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201215001; called by muse, mutect2, varscan2
- N4BP2 | c.4339T>G p.L1447V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.048); catalogued as COSV99788092; called by muse, mutect2
- NCKAP5 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as COSV100491164; called by muse, mutect2, varscan2
- ODF2L | c.1518+1G>T p.X506_splice (on ENST00000317336; = p.X477_splice on NM_020729.3) | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as rs756639946, COSV99643736; called by muse, mutect2, varscan2
- OR10X1 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 23/375 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100936567; called by muse, mutect2
- OR2A14 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV68717924; called by muse, mutect2
- OR2B2 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV57580222; called by muse, mutect2, varscan2
- OR4K1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs755426984, COSV53459544, COSV99579075; called by muse, mutect2, varscan2
- PCDH15 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57352208, COSV57353314; called by muse, mutect2, varscan2
- PCDHA1 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100974237; called by muse, mutect2
- PCDHA3 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs1274408864, COSV63542512; called by muse, mutect2, varscan2
- PDE1A | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1418750796, COSV100113096; called by muse, mutect2, varscan2
- POLRMT | c.3230C>G p.P1077R | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52114599, COSV52117045; called by muse, mutect2
- POLRMT | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1213176268, COSV52112547, COSV52117071; called by muse, mutect2, varscan2
- PPP1CC | c.902A>C p.K301T | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as COSV58584318; called by muse, mutect2, varscan2
- PSMD13 | c.1087A>G p.M363V | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as rs746014086; called by muse, mutect2, varscan2
- PXDN | c.3386G>A p.R1129H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs117378371, COSV53241438, COSV53250146; called by muse, mutect2, varscan2
- PXDNL | c.2193C>A p.D731E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV62484401, COSV62493539; called by muse, varscan2
- RADX | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 117/254 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV65320392; called by muse, mutect2, varscan2
- RBMXL3 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as COSV57756287; called by muse, mutect2
- RETNLB | c.306G>C p.W102C | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99848680; called by muse, mutect2, varscan2
- RIMBP3 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs765388773; called by muse, mutect2, varscan2
- RPS6KA6 | c.327del p.A110Pfs*3 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs756096568; called by mutect2, pindel, varscan2
- RTP5 | c.1654G>T p.V552L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV58319002, COSV58321074; called by muse, mutect2, varscan2
- SAGE1 | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as COSV61013642; called by muse, mutect2
- SHANK2 | c.3929C>T p.S1310L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1555153534, COSV99573941; called by muse, mutect2, varscan2
- SHISA4 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755134716; called by muse, mutect2, varscan2
- SLC35G3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs1365396709, COSV52012703; called by muse, mutect2
- SLCO3A1 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs554567337, COSV100574845, COSV59236206; called by muse, mutect2
- SLIT3 | c.1684A>T p.I562L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.959); catalogued as COSV100270799; called by muse, mutect2, varscan2
- SNX33 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435102212, COSV100145705; called by muse, mutect2
- SOX10 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs758445473; called by muse, mutect2, varscan2
- SOX11 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100430658, COSV58985912; called by muse, mutect2, varscan2
- SPATA19 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV54482477, COSV54484209; called by muse, mutect2, varscan2
- SPTB | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139094636; called by muse, mutect2, varscan2
- STK38 | c.1253T>G p.I418S | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as rs746316301, COSV57709857; called by muse, mutect2, varscan2
- STX11 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62448985; called by muse, mutect2
- TAPBP | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.038); catalogued as rs749133011, COSV70457449; called by muse, mutect2, varscan2
- TBL1X | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as COSV54284231; called by muse, mutect2, varscan2
- TCF7L2 | c.583_584insT p.H195Lfs*15 (on ENST00000355995 / NM_001367943.1; = p.H172Lfs*15 on NM_030756.5) | Frame Shift Ins (INS) | VAF 9/95 reads (9%) | catalogued as COSV53344719; called by mutect2, pindel, varscan2
- TNC | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370926474; called by muse, mutect2, varscan2
- TRPM2 | c.3728G>A p.R1243Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs201821709, COSV100308035; called by muse, mutect2, varscan2
- TTBK1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1398796119, COSV52494130; called by muse, mutect2, varscan2
- TUSC3 | c.1028G>T p.S343I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as CM158805; called by muse, mutect2, varscan2
- VPS13C | c.4879A>G p.M1627V (on ENST00000644861 / NM_020821.3; = p.M1584V on NM_017684.5) | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1347287752, COSV51133031; called by muse, mutect2, varscan2
- WASF3 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs749653652; called by muse, mutect2, varscan2
- ZNF705A | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV63733802; called by muse, mutect2
- ALG2 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- APC | c.3614del p.S1205Tfs*60 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- BRWD3 | c.4478C>A p.S1493Y | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CAND1 | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CARMIL3 | c.2031G>T p.Q677H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CARMIL3 | c.2695G>T p.G899W | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CC2D2A | c.4109T>C p.V1370A | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCL17 | c.174del p.R59Gfs*7 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel
- CDC42EP4 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC4E | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CNNM3 | c.1126T>G p.C376G | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2
- ENPP3 | c.430T>C p.C144R | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ERBIN | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERI2 | c.1306A>G p.I436V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, varscan2
- FAM83B | c.1779del p.K593Nfs*30 | Frame Shift Del (DEL) | VAF 45/144 reads (31%) | called by mutect2, pindel, varscan2
- FBXL2 | c.291-7del | Splice Region (DEL) | VAF 41/130 reads (32%) | called by mutect2, pindel, varscan2
- FREM2 | c.8607G>C p.K2869N | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- HNRNPAB | c.431dup p.A145Gfs*20 | Frame Shift Ins (INS) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- HTR7 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IGF2R | c.3292G>A p.G1098S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- KCNH1 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 220/319 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIAA1755 | c.2323G>T p.D775Y | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LEF1 | c.976A>G p.S326G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEA3 | c.790A>C p.S264R | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MAP3K4 | c.683C>G p.T228S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NLGN3 | c.1748C>T p.T583I (on ENST00000358741 / NM_181303.2; = p.T563I on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- OR6T1 | c.929T>A p.L310H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.443); called by muse, mutect2
- PHYH | c.861C>A p.C287* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- PLK1 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNC1 | c.1514dup p.C506Vfs*3 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel
- PTPN12 | c.2056G>T p.V686L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- RHOC | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SOX9 | c.698del p.G233Afs*20 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | called by mutect2, pindel, varscan2
- TAB2 | c.1860A>G p.G620= | Splice Region (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- TAF3 | c.2069T>G p.F690C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TNXB | c.2080C>A p.P694T | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRIM24 | c.3112A>G p.K1038E (on ENST00000343526 / NM_015905.3; = p.K1004E on NM_003852.4) | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- UNC80 | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- VPS50 | c.1826A>G p.N609S | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- WNT10A | c.194C>G p.P65R | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNHIT6 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS20 | c.4888C>A p.R1630= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV101238712, COSV67130295; called by muse, mutect2, varscan2
- AK1 | c.357C>T p.D119= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs1225543302, COSV56344730; called by muse, mutect2
- ATP9B | c.2166C>T p.A722= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs559792996, COSV56950977; called by muse, mutect2, varscan2
- BPIFB3 | c.900C>T p.L300= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs746212339; called by muse, mutect2, varscan2
- CCDC168 | c.11748G>A p.P3916= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs756666805, COSV59423433; called by muse, mutect2, varscan2
- CHST11 | c.768C>T p.N256= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as rs141249414; called by muse, mutect2, varscan2
- CTNND2 | c.1875C>T p.N625= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs375489164; called by muse, mutect2, varscan2
- DDX17 | c.39G>A p.L13= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs1199668824, COSV99318514; called by muse, mutect2, varscan2
- DOCK11 | c.2709C>T p.C903= | Silent (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- FAM110B | c.873G>T p.L291= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- FAT3 | c.11847G>A p.T3949= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV53145020; called by muse, mutect2, varscan2
- FBXO44 | c.363G>A p.Q121= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99278693; called by muse, mutect2
- GRTP1 | c.702C>T p.F234= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs1050608708, COSV58151072; called by muse, mutect2, varscan2
- H1-5 | c.480G>A p.K160= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs764722398, COSV58899214, COSV58899740, COSV58899833; called by muse, mutect2, varscan2
- HECTD1 | c.2724A>G p.P908= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as rs1566625243; called by muse, mutect2, varscan2
- HOMER2 | c.375T>C p.S125= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- INA | c.666C>T p.D222= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- INF2 | c.3435C>T p.A1145= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs780026536, COSV53034420; called by muse, mutect2, varscan2
- NUPR2 | c.72C>T p.Y24= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100253710; called by muse, mutect2, varscan2
- OBSCN | c.11190G>A p.T3730= | Silent (SNP) | VAF 27/421 reads (6%) | catalogued as rs78314897; called by muse, mutect2
- OR2T33 | c.558T>C p.A186= | Silent (SNP) | VAF 56/404 reads (14%) | catalogued as COSV100531478; called by muse, varscan2
- OR6F1 | c.720G>A p.T240= | Silent (SNP) | VAF 20/195 reads (10%) | catalogued as rs376931741; called by muse, mutect2, varscan2
- PCDHA3 | c.429C>T p.S143= | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.2130A>T p.V710= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV53958979; called by muse, mutect2, varscan2
- PLD5 | c.621G>A p.T207= (on ENST00000442594; = p.T145= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 113/189 reads (60%) | catalogued as rs369597039, COSV100139900; called by muse, mutect2, varscan2
- POTEE | c.2520G>A p.P840= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs778754830, COSV58231409; called by muse, mutect2
- POU4F2 | c.561G>A p.A187= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs376581460, COSV55585785; called by muse, mutect2, varscan2
- RDH13 | c.649C>A p.R217= (on ENST00000415061 / NM_001145971.2; = p.R146= on NM_138412.4) | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs370269755, COSV52561489; called by muse, mutect2, varscan2
- RUSC1 | c.600C>T p.D200= | Silent (SNP) | VAF 36/228 reads (16%) | called by muse, mutect2, varscan2
- SCN1A | c.1842C>T p.H614= | Silent (SNP) | VAF 45/264 reads (17%) | catalogued as rs370463183; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK1 | c.3231C>A p.V1077= | Silent (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- SERPINA6 | c.1137C>T p.F379= | Silent (SNP) | VAF 91/225 reads (40%) | catalogued as COSV58586367; called by muse, mutect2, varscan2
- SLC27A5 | c.1953G>A p.E651= | Silent (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- STIM2 | c.1866G>A p.P622= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs757441641, COSV52841235; called by muse, mutect2
- TMC1 | c.1599G>C p.L533= | Silent (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- TOR3A | c.774G>A p.E258= | Silent (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- UBAP2L | c.2103G>A p.Q701= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as rs1342532249; called by muse, mutect2, varscan2
- UNC13D | c.663G>A p.T221= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs771266801, COSV52884022; called by muse, mutect2, varscan2
- CPXCR1 | c.*337_*340del | 3'UTR (DEL) | VAF 41/126 reads (33%) | called by mutect2, pindel, varscan2
- FBLN2 | c.2155+2080C>T | Intron (SNP) | VAF 24/44 reads (55%) | catalogued as rs373727437, COSV55481026, COSV99852134; called by muse, mutect2, varscan2
- FOXO4 | c.*44G>A | 3'UTR (SNP) | VAF 21/40 reads (53%) | catalogued as COSV100446747; called by muse, mutect2, varscan2
- MIR1270 | chr19:20398729 A>T | 3'Flank (SNP) | VAF 7/42 reads (17%) | called by muse, varscan2
- OLIG1 | c.*618G>A | 3'UTR (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100287117; called by muse, mutect2, varscan2
- PRR9 | c.*526A>T | 3'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- RFX4 | c.44-7459G>A | Intron (SNP) | VAF 62/188 reads (33%) | catalogued as rs375854420; called by muse, varscan2
- RPL13AP25 | n.415G>T | RNA (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- SEC13 | c.4-1110C>T | Intron (SNP) | VAF 155/340 reads (46%) | called by muse, mutect2, varscan2
